Gene-level copy-number profile of tumor specimen TCGA-N5-A4RN-01A from TCGA case TCGA-N5-A4RN, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 71.3 years (26,054 days).
Specimen TCGA-N5-A4RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.2b9b1fe1-9a48-4ed8-afb4-b64d847b3985.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c50a8c51-52d2-416f-b477-7b9af79bcf00

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 432; copy number 2: 15,230; copy number 3: 24,450; copy number 4: 10,442; copy number 5: 6,384; copy number 6: 1,595; copy number 7: 321; copy number 8: 463; copy number 9: 236; copy number 10: 36; copy number 13: 158; copy number 16: 48; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RN-01A-12D-A28Q-01): tumor purity 0.93, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,245 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:147,060,613–148,072,776, 16 genes, copy number 7: AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1.
- chr5:58,198–2,788,549, 84 genes, copy number 10–16 (broad region; genes not listed).
- chr6:36,697,826–36,839,444, 4 genes, copy number 8 (within-gene range 5–8): RAB44, Z85996.1, CPNE5, Z85996.2.
- chr6:49,077,712–57,961,501, 149 genes, copy number 9–13 (broad region; genes not listed).
- chr6:57,967,687–58,121,029, 3 genes, copy number 13: GAPDHP15, AL390237.1, RBBP4P4.
- chr7:70,972–16,502,504, 269 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:16,471,184–16,471,373, 1 gene, copy number 7: AC005014.3.
- chr7:63,843,314–66,915,334, 143 genes, copy number 8 (broad region; genes not listed).
- chr8:31,339,197–43,674,591, 236 genes, copy number 9–17 (broad region; genes not listed).
- chr13:86,909,586–87,674,235, 8 genes, copy number 7 (within-gene range 4–7): LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500.
- chr18:20,946,906–46,128,333, 332 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
